Somatic mutation profile of tumor specimen MMRF_2559_1_BM_CD138pos (aliquot MMRF_2559_1_BM_CD138pos_T1_KHS5U_K15158) from MMRF case MMRF_2559, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 51.9 years (18,945 days).
Specimen MMRF_2559_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1f6bcb34-20a6-4c00-bd50-d0474e5b6b7f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2559_2_PB_Whole (Blood Derived Normal), aliquot MMRF_2559_2_PB_Whole_C1_KHS5U_K15157; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3ff7e315-9267-4046-8e00-cf80695f2dcc

The open-access MAF lists 79 somatic variants for this specimen: 26 protein-altering or splice-affecting, 13 silent, 40 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, 3'UTR 19, Silent 13, Intron 11, 5'Flank 4, Nonsense Mutation 3, Frame Shift Ins 2, RNA 2, 3'Flank 2, 5'UTR 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AREG | c.334dup p.Q112Pfs*7 | Frame Shift Ins (INS) | VAF 78/182 reads (43%) | catalogued as rs757742243; called by mutect2, varscan2
- CLEC1A | c.761G>A p.R254H | Missense Mutation (SNP) | VAF 125/255 reads (49%) | SIFT tolerated (0.47); PolyPhen benign (0.208); catalogued as rs147882348, COSV100191187, COSV59531017; called by muse, mutect2, varscan2
- COL15A1 | c.3167G>T p.G1056V | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100898062; called by muse, mutect2, varscan2
- GTF3C1 | c.5542G>A p.E1848K | Missense Mutation (SNP) | VAF 57/126 reads (45%) | SIFT tolerated (0.5); PolyPhen benign (0.1); catalogued as rs750603013, COSV62240609; called by muse, mutect2, varscan2
- IGHV2-70 | c.304A>T p.T102S | Missense Mutation (SNP) | VAF 49/60 reads (82%) | SIFT tolerated (0.21); PolyPhen benign (0.062); catalogued as rs373390524; called by muse, varscan2
- IGLV3-1 | c.334A>G p.S112G | Missense Mutation (SNP) | VAF 84/92 reads (91%) | SIFT tolerated (0.09); PolyPhen benign (0.089); catalogued as rs370589387; called by muse, mutect2, varscan2
- IGLV3-21 | c.200A>C p.Y67S | Missense Mutation (SNP) | VAF 79/136 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); catalogued as rs376214331; called by muse, mutect2, varscan2
- IGLV3-21 | c.290A>G p.E97G | Missense Mutation (SNP) | VAF 65/149 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.138); catalogued as rs373184711; called by muse, varscan2
- IGLV5-45 | c.110C>T p.A37V | Missense Mutation (SNP) | VAF 156/372 reads (42%) | SIFT tolerated (0.47); PolyPhen benign (0.136); catalogued as rs761673710; called by muse, mutect2, varscan2
- MFSD10 | c.1184C>T p.T395M | Missense Mutation (SNP) | VAF 85/139 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs780371378; called by muse, mutect2, varscan2
- NPAS4 | c.209C>A p.S70* | Nonsense Mutation (SNP) | VAF 49/99 reads (49%) | catalogued as rs1437838063; called by muse, mutect2, varscan2
- PI4KA | c.4111C>T p.R1371C | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as rs1352953187, COSV55415266; called by muse, varscan2
- PKD1L1 | c.5638G>A p.V1880M | Missense Mutation (SNP) | VAF 88/220 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.845); catalogued as rs1351524560; called by muse, mutect2, varscan2
- TOMM40 | c.962A>G p.N321S | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.444); catalogued as rs1375926207; called by muse, mutect2, varscan2
- A1BG | c.1474G>A p.V492M | Missense Mutation (SNP) | VAF 55/124 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAJC25 | c.440A>C p.D147A | Missense Mutation (SNP) | VAF 46/115 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ECM2 | c.1247T>G p.L416* | Nonsense Mutation (SNP) | VAF 22/54 reads (41%) | called by muse, mutect2, varscan2
- FAM189A2 | c.1320C>A p.S440R | Missense Mutation (SNP) | VAF 80/172 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HAPLN1 | c.299A>C p.Y100S | Missense Mutation (SNP) | VAF 90/182 reads (49%) | SIFT tolerated (0.56); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- IGHV2-70 | c.343_356del p.Y115_I119del | Frame Shift Del (DEL) | VAF 22/34 reads (65%) | called by pindel, varscan2
- NARS1 | c.770G>A p.R257K | Missense Mutation (SNP) | VAF 41/129 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- PCDH10 | c.794dup p.G266Rfs*19 | Frame Shift Ins (INS) | VAF 146/399 reads (37%) | called by mutect2, pindel, varscan2
- SULT2A1 | c.411G>A p.M137I | Missense Mutation (SNP) | VAF 77/150 reads (51%) | SIFT tolerated (0.49); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TRIM17 | c.827G>T p.R276I | Missense Mutation (SNP) | VAF 96/352 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- USP31 | c.242A>T p.E81V | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- VWC2 | c.966C>A p.C322* | Nonsense Mutation (SNP) | VAF 135/352 reads (38%) | called by muse, mutect2, varscan2
- ARAP1 | c.2022C>T p.D674= (on ENST00000393609 / NM_001040118.2; = p.D429= on NM_015242.4) | Silent (SNP) | VAF 58/110 reads (53%) | catalogued as rs1158953683; called by muse, mutect2, varscan2
- DENND5B | c.78G>A p.V26= | Silent (SNP) | VAF 12/26 reads (46%) | called by muse, varscan2
- ERN1 | c.1611C>G p.L537= | Silent (SNP) | VAF 25/89 reads (28%) | called by muse, varscan2
- FARS2 | c.333G>A p.S111= | Silent (SNP) | VAF 142/301 reads (47%) | catalogued as rs781723007; called by muse, mutect2, varscan2
- IGHV2-70D | c.282C>G p.T94= | Silent (SNP) | VAF 62/130 reads (48%) | catalogued as rs1379044949; called by muse, varscan2
- IGHV2-70D | c.237C>T p.F79= | Silent (SNP) | VAF 80/174 reads (46%) | called by muse, varscan2
- IGHV3-30 | c.336G>A p.V112= | Silent (SNP) | VAF 83/86 reads (97%) | catalogued as rs771431417; called by muse, mutect2, varscan2
- IGLV3-19 | c.66G>A p.E22= | Silent (SNP) | VAF 32/81 reads (40%) | catalogued as rs149439245; called by muse, mutect2, varscan2
- IGLV3-19 | c.67C>T p.L23= | Silent (SNP) | VAF 32/82 reads (39%) | catalogued as rs549439317; called by muse, mutect2, varscan2
- PLEKHM3 | c.1731C>T p.Y577= | Silent (SNP) | VAF 148/299 reads (49%) | catalogued as rs748553172, COSV66816232; called by muse, mutect2, varscan2
- RPS6KB2 | c.1044T>C p.C348= | Silent (SNP) | VAF 140/295 reads (47%) | called by muse, mutect2, varscan2
- STOML2 | c.501C>T p.C167= | Silent (SNP) | VAF 36/76 reads (47%) | catalogued as rs778287057; called by muse, mutect2, varscan2
- ZFP36L1 | c.37T>C p.L13= | Silent (SNP) | VAF 43/45 reads (96%) | called by muse, varscan2
- ACSS3 | c.*4362T>G | 3'UTR (SNP) | VAF 37/75 reads (49%) | called by muse, mutect2, varscan2
- ADAM11 | c.*389G>A | 3'UTR (SNP) | VAF 11/198 reads (6%) | called by muse, mutect2
- ADGRL2 | c.3625+963G>A | Intron (SNP) | VAF 27/66 reads (41%) | called by muse, mutect2, varscan2
- AL449403.2 | n.200A>T | RNA (SNP) | VAF 22/56 reads (39%) | called by muse, mutect2, varscan2
- APOA2 | c.52+135G>T | Intron (SNP) | VAF 45/91 reads (49%) | catalogued as COSV99248263; called by muse, mutect2, varscan2
- BIRC6 | c.12291+686A>G | Intron (SNP) | VAF 6/17 reads (35%) | called by muse, mutect2, varscan2
- CARNMT1 | c.*677G>C | 3'UTR (SNP) | VAF 3/17 reads (18%) | called by muse, mutect2
- CDSN | c.*88T>C | 3'UTR (SNP) | VAF 35/140 reads (25%) | called by muse, mutect2, varscan2
- CEP43 | c.*2418A>C | 3'UTR (SNP) | VAF 30/65 reads (46%) | called by muse, mutect2, varscan2
- CRIP2 | c.502-82G>A | Intron (SNP) | VAF 53/59 reads (90%) | called by muse, mutect2, varscan2
- DPYD | c.483+917A>C | Intron (SNP) | VAF 19/39 reads (49%) | called by muse, mutect2, varscan2
- FAM32EP | chr12:126458011 T>C | 3'Flank (SNP) | VAF 36/85 reads (42%) | called by muse, mutect2, varscan2
- GOSR1 | c.-21G>A | 5'UTR (SNP) | VAF 65/150 reads (43%) | called by muse, mutect2, varscan2
- HAP1 | c.*237G>A | 3'UTR (SNP) | VAF 49/94 reads (52%) | catalogued as rs1490938586; called by muse, mutect2, varscan2
- IGF2BP2 | c.240-19774A>T | Intron (SNP) | VAF 39/78 reads (50%) | called by muse, mutect2, varscan2
- LYPLAL1 | c.*1030C>T | 3'UTR (SNP) | VAF 28/75 reads (37%) | called by muse, mutect2, varscan2
- ME1 | c.*596A>C | 3'UTR (SNP) | VAF 6/82 reads (7%) | called by muse, mutect2
- MGAT4A | c.*5549G>A | 3'UTR (SNP) | VAF 3/49 reads (6%) | called by muse, mutect2
- MIR5195 | chr14:106851312 T>G | 5'Flank (SNP) | VAF 97/262 reads (37%) | catalogued as rs1376536873; called by muse, mutect2, varscan2
- MYO1E | c.*32G>C | 3'UTR (SNP) | VAF 19/78 reads (24%) | catalogued as rs777328038; called by muse, mutect2, varscan2
- MYO1E | c.-111C>G | 5'UTR (SNP) | VAF 78/155 reads (50%) | called by muse, varscan2
- NAA25 | c.*82C>T | 3'UTR (SNP) | VAF 118/253 reads (47%) | called by muse, mutect2, varscan2
- NELFA | c.668-86T>G | Intron (SNP) | VAF 26/54 reads (48%) | called by muse, mutect2, varscan2
- NR4A3 | c.1254+423A>C | Intron (SNP) | VAF 46/97 reads (47%) | called by muse, mutect2, varscan2
- NRXN1 | c.4039-30235T>C | Intron (SNP) | VAF 59/138 reads (43%) | called by muse, mutect2, varscan2
- OR9Q2 | chr11:58190432 C>T | 5'Flank (SNP) | VAF 10/168 reads (6%) | called by muse, mutect2
- PRRG4 | c.*483C>G | 3'UTR (SNP) | VAF 7/141 reads (5%) | called by muse, mutect2
- QSOX1 | c.*2970G>T | 3'UTR (SNP) | VAF 62/135 reads (46%) | called by muse, mutect2, varscan2
- RPS6KB1 | c.*750G>C | 3'UTR (SNP) | VAF 16/289 reads (6%) | called by muse, mutect2
- RPS6KB1 | c.*751T>A | 3'UTR (SNP) | VAF 16/287 reads (6%) | called by muse, mutect2
- SEL1L3 | chr4:25863479 T>C | 5'Flank (SNP) | VAF 169/317 reads (53%) | called by muse, mutect2, varscan2
- SGCD | c.*7587G>A | 3'UTR (SNP) | VAF 35/80 reads (44%) | called by muse, mutect2, varscan2
- SLC25A21 | chr14:37173612 T>G | 5'Flank (SNP) | VAF 27/29 reads (93%) | called by muse, mutect2, varscan2
- SNORD116-23 | n.14C>A | RNA (SNP) | VAF 7/63 reads (11%) | called by muse, mutect2
- SNX20 | chr16:50668569 A>G | 3'Flank (SNP) | VAF 33/93 reads (35%) | called by muse, mutect2, varscan2
- STAM2 | c.*1041A>G | 3'UTR (SNP) | VAF 46/142 reads (32%) | called by muse, mutect2, varscan2
- SYNE1 | c.26154-3069T>G | Intron (SNP) | VAF 49/89 reads (55%) | called by muse, mutect2, varscan2
- TAFA2 | c.*1329T>A | 3'UTR (SNP) | VAF 48/114 reads (42%) | called by muse, mutect2, varscan2
- TMEM47 | c.*454A>T | 3'UTR (SNP) | VAF 61/62 reads (98%) | called by muse, mutect2, varscan2
- UTP6 | c.967+58C>T | Intron (SNP) | VAF 40/93 reads (43%) | called by muse, mutect2, varscan2
